Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5746, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5746-01A (Primary Tumor).

TCGA-CH-5746

Diagnosis

1. Predominantly moderately differentiated adenocarcinoma of the prostate on both sides with left rectolateral predominance. Maximum tumor spread 1.5 cm. No identifiable invasion of the vessels and no extraprostatic tumor growth. Tumor-free seminal vesicles. Infiltration of the surgical margins in the left rectolateral and basal resection.
2. Tumor-free fatty tissue.
3. Fatty tissue with two tumor-free lymph nodes.

Remark

In summary, the tumor classification is as follows:

pT2c, pN0 (0/2), L0, V0; Gleason 3+4 = 7 (approx. 40% Gleason 4).

In the region of the tissue defects, carcinoma cells extend to the yellow labeled preparation margin (yellow labeling).

Additionally, in the left apex and in the first disk in the left rectolateral region there is focal contact with the blue labeling (contact surface max. 2 mm, in total 3 mm wide).

Source: NCI Genomic Data Commons file c4fbd199-3c82-45ee-baf1-b78283fc0dbc (TCGA-CH-5746.4DED5042-7CA5-46EB-AE44-1DD4C7A38C9E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).